Somatic mutation profile of tumor specimen MP2PRT-PARKBL-TBP1-A (aliquot MP2PRT-PARKBL-TBP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARKBL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (973 days).
Specimen MP2PRT-PARKBL-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 213f14d8-7063-462a-8597-e1efcca581c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARKBL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARKBL-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e98c9473-d164-4f9e-b91e-f8db518a4aa1

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 158/319 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRT75 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 142/433 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as rs551607862; called by muse, mutect2, varscan2
- SFXN4 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 130/486 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs1313718887; called by muse, mutect2, varscan2
- SYNJ2 | c.3200C>T p.T1067M | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.733); catalogued as rs140015862; called by muse, mutect2, varscan2
- TRIM72 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 190/392 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs745643982; called by muse, mutect2, varscan2
- MXRA5 | c.7869C>A p.G2623= | Silent (SNP) | VAF 301/558 reads (54%) | catalogued as rs1404776722; called by muse, mutect2, varscan2
